CCDI case PBBLSB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/1171281b-3dc7-46de-85d5-7cdd63cf100f

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Undifferentiated sarcoma: ICD-O-3 morphology code: 8805/3; Tissue or organ of origin: Bones of skull and face and associated joints; Age at diagnosis: 0.5 years (183 days).

Biospecimens (3 samples)
- Sample 0DBU0J: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DBU0W: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DBU0Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
